Somatic mutation profile of tumor specimen TCGA-QR-A6GS-01A (aliquot TCGA-QR-A6GS-01A-11D-A35D-08) from TCGA case TCGA-QR-A6GS, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 51.5 years (18,798 days).
Specimen TCGA-QR-A6GS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6de719b6-a8d6-401d-80c9-d63bc17c60a9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A6GS-10A (Blood Derived Normal), aliquot TCGA-QR-A6GS-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b924088-d92a-4ccd-a744-67a0059a0221

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 2, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.1527+1G>T p.X509_splice | Splice Site (SNP) | VAF 9/13 reads (69%) | catalogued as rs1060500331, CD000959, CS040856, CS086407, CS993383, COSV62203118, COSV62217322; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HMCN1 | c.1205T>G p.F402C | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV54947016; called by muse, mutect2, varscan2
- MYO18B | c.6233C>T p.A2078V | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.25); catalogued as COSV59129131; called by muse, mutect2
- NAPB | c.346A>T p.R116W | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373515530; called by muse, mutect2, varscan2
- PTPN14 | c.2918G>C p.G973A | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV65284611; called by muse, mutect2
- GCHFR | c.225G>C p.Q75H | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDE4D | c.1627C>A p.L543I (on ENST00000340635 / NM_001104631.2; = p.L407I on NM_006203.4) | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SH3TC1 | c.3856A>G p.I1286V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- RBM47 | c.618G>A p.A206= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as rs1189983075; called by muse, mutect2
- SCUBE1 | c.2364C>A p.T788= | Silent (SNP) | VAF 17/54 reads (31%) | called by muse, mutect2, varscan2
- ZNF324B | c.-59G>A | 5'UTR (SNP) | VAF 9/42 reads (21%) | catalogued as rs769375040; called by muse, mutect2, varscan2
